Gene-level copy-number profile of tumor specimen TCGA-OY-A56P-01A from TCGA case TCGA-OY-A56P, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 48.1 years (17,580 days).
Specimen TCGA-OY-A56P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.efb6506d-f0d6-49e8-8e5f-35780806bc66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OY-A56P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e0c9ba95-6503-485a-a268-cf300b616ef0

Most common (modal) total copy number across autosomal genes: 7 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 2: 3,929; copy number 3: 10,868; copy number 4: 11,438; copy number 5: 11,690; copy number 6: 3,812; copy number 7: 13,137; copy number 8: 3,141; copy number 9: 1,118; copy number 10: 55; copy number 11: 258; copy number 12: 41; copy number 13: 6; copy number 17: 56; copy number 18: 27; copy number 20: 2; copy number 21: 12; copy number 22: 62; copy number 24: 8; copy number 28: 23; copy number 33: 16; copy number 42: 59; copy number 55: 36; copy number 69: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OY-A56P-01A-12D-A402-01): tumor purity 0.96, ploidy 5.19, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 15, i.e. more than twice the modal value of 7; autosomes only): 308 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:23,108,458–32,993,754, 203 genes, copy number 18–69 (broad region; genes not listed).
- chr12:41,188,320–41,574,745, 2 genes, copy number 20: PDZRN4, AC090531.1.
- chr12:43,560,784–46,876,784, 47 genes, copy number 18–33 (within-gene range 5–33): AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1.
- chr19:16,719,847–17,788,568, 56 genes, copy number 17 (within-gene range 7–17): NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3, CPAMD8, RN7SL835P, RN7SL823P, AC020908.2, HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
